Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4VE, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4VE-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BOTH OVARIES AND FALLOPIAN TUBES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (140 GRAMS) -

- A. ENDOMETRIUM WITH MALIGNANT MIXED MULLERIAN TUMOR, HETEROLOGOUS-TYPE, INVOLVING ABOUT 70% OF ENDOMETRIAL SURFACE, LIMITED TO THE ENDOMETRIUM, AND EXTENDING INTO LOWER UTERINE SEGMENT AND RIGHT LATERAL ENDOCERVICAL CANAL WITH FULL THICKNESS PENETRATION INTO THE SEROSA AND THE RIGHT PARAMETRIUM (see comment).
- B. ENDOMETRIAL POLYP INVOLVED WITH TUMOR.
- C. UNINVOLVED ENDOMETRIUM IN PROLIFERATIVE PATTERN WITH CYSTIC CHANGES.
- D. ADENOMYOSIS.
- E. MULTIPLE LEIOMYOMA, UP TO 1.2 CM, LARGEST WITH HYALINIZATION.
- F. MEDIAL CALCIFICATION OF MYOMETRIAL BLOOD VESSELS.
- G. UTERINE CERVIX CONTAINING TUMOR INVOLVING FULL THICKNESS OF THE CERVICAL WALL WITH EXTENSIVE LYMPHOVASCULAR PERMEATION.
- H. CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA.
- I. VAGINAL MARGIN INVOLVED WITH TUMOR AND SHOWING EXTENSIVE LYMPHOVASCULAR PERMEATION.
- J. UTERINE SEROSA INVOLVED WITH TUMOR.
- K. LEFT OVARY WITH ENDOMETRIOSIS, CALCIFICATION, EPITHELIAL INCLUSIONS AND SEROSAL ADHESIONS, NO TUMOR SEEN.
- L. RIGHT OVARY WITH EPITHELIAL INCLUSIONS, NOT TUMOR SEEN.
- M. RIGHT AND LEFT FALLOPIAN TUBES, NO TUMOR SEEN.

PART 2: SOFT TISSUE, RIGHT PARAMETRIUM WITH NODE, BIOPSY -
METASTATIC MALIGNANT MIXED MULLERIAN TUMOR INVOLVING TWO OF TWO LYMPH NODES (2/2)
WITH
EXTRACAPSULAR EXTENSION, UP TO 2.7 CM.

PART 3: LYMPH NODE, RIGHT COMMON ILIAC, BIOPSY -
METASTATIC MALIGNANT MIXED MULLERIAN TUMOR INVOLVING ONE LYMPH NODE (1/1), UP TO 0.2 CM.

PART 4: LYMPH NODE, RIGHT PERIAORTIC, BIOPSY -
METASTATIC MALIGNANT MIXED MULLERIAN TUMOR INVOLVING ONE LYMPH NODE (1/1), UP TO 0.2 CM.

PART 5: LYMPH NODE, RIGHT EXTERNAL ILIAC, BIOPSY -
METASTATIC MALIGNANT MIXED MULLERIAN TUMOR INVOLVING ONE LYMPH NODE (1/1), UP TO 0.2 CM.

PART 6: LYMPH NODE, LEFT COMMON ILIAC, BIOPSY -
TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 7: LYMPH NODE, LEFT PERIAORTIC, BIOPSY -
TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 8: LYMPH NODE, LEFT EXTERNAL ILIAC, BIOPSY -
FOUR LYMPH NODES, FREE OF TUMOR (0/4).

PART 9: OMENTUM, OMENTECTOMY -
OMENTUM, NO TUMOR SEEN.

COMMENT:

Immunohistochemical staining for vimentin and cytokeratin, CAM 5.2, support the above diagnosis. The metastatic tumor is mainly composed of sarcomatous component of the malignant mixed mullerian tumor. Selected slide of this case was also reviewed by Dr. , who concurs with the above diagnosis. This endometrial cancer represent a malignant mixed mullerian tumor, FIGO stage 3C. Peritoneal cytology is negative. Correlated with previous surgical specimen.

MICROSCOPIC:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Carcinosarcoma (malignant mixed mesodermal tumor)
[combined architectural and nuclear]

ARCHITECTURAL GRADE: Poorly differentiated (FIGO 3)
NUCLEAR GRADE: Poorly differentiated
Grade 3

TUMOR SIZE**: Maximum dimension: 5 cm
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT**: Anterior endomyometrium: 80 %, Posterior endomyometrium: 60 %

DEPTH OF INVASION**: No invasion
STRUCTURES INVOLVED: Cervical stroma, Vagina
MARGINS OF RESECTION: Vaginal margin is positive for tumor, Parametrium margin is positive for tumor
ANGIOLYMPHATIC INVASION: Yes
OTHER: (epithelial, smooth muscle, others), Endometrial polyp, Adenomyosis, Leiomyoma
LYMPH NODES POSITIVE: Number of lymph nodes positive:: 5
LYMPH NODES EXAMINED: Total number of lymph nodes examined: 13
LYMPH NODE GROUPS INVOLVED: Pelvic lymph nodes, Right, Common iliac lymph nodes, Right, Parametrial lymph nodes, Right, Para-aortic lymph nodes, Right

EXTRANODAL EXTENSION: Yes
(excludes metastases to vagina, pelvic serosa, and adnexa. Includes lymph nodes other than regional lymph nodes.)

T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN1
M STAGE, PATHOLOGIC: pMX
FIGO STAGE: IIIC

ICD-O-3
Carcinosarcoma, Mixed Mullerian Tumor,
malignant 8950/3
Site Corpus Uteri, Endometrium C54.1
JW 6/28/13

Criteria	W 12/31/12	Yes	No
ICD-10 Discrepancy			
Primary Malignancy History			
Pathologic/Primary Discrepancy			
Case in (circle):	QUALIFIED	UNQUALIFIED	

Source: NCI Genomic Data Commons file ba9dd4a5-897a-4470-8285-180883b40f61 (TCGA-N6-A4VE.2619DFD3-EE8B-4199-87B2-2E5E378386EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).